Gene-level copy-number profile of tumor specimen TCGA-24-1544-01A from TCGA case TCGA-24-1544, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.6 years (26,141 days).
Specimen TCGA-24-1544-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7cce06da-3bb9-44e1-b971-e87ea08505d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1544-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/733947c6-449b-4a5e-8d61-d57b52e24d45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,158; copy number 2: 22,719; copy number 3: 19,720; copy number 4: 13,032; copy number 5: 1,965; copy number 6: 418; copy number 7: 191; copy number 8: 134; copy number 9: 85; copy number 10: 83; copy number 12: 161; copy number 13: 121; copy number 14: 23; copy number 16: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1544-01): tumor purity 0.93, ploidy 3.05, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,184 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:214,281,102–214,664,571, 8 genes, copy number 5: SMYD2, AL929236.1, PTPN14, AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13.
- chr3:161,816,909–198,222,513, 646 genes, copy number 5 (broad region; genes not listed).
- chr4:49,096–5,019,458, 155 genes, copy number 5–6 (broad region; genes not listed).
- chr4:57,109,762–57,207,459, 1 gene, copy number 5 (within-gene range 2–5): IGFBP7-AS1.
- chr4:57,154,577–57,855,271, 8 genes, copy number 5: AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1.
- chr5:12,553,890–16,465,800, 44 genes, copy number 7–16: AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN, ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, AC016575.2, U8, LINC02149, MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622.
- chr5:16,853,994–16,941,951, 3 genes, copy number 7: RNA5SP179, RPS26P28, RNU6-660P.
- chr5:17,089,296–17,217,047, 4 genes, copy number 7 (within-gene range 4–7): BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180.
- chr5:20,830,166–28,809,291, 73 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr5:29,304,305–30,743,704, 12 genes, copy number 6–7 (within-gene range 4–7): LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1, AC026433.1.
- chr5:31,639,131–32,110,932, 1 gene, copy number 5 (within-gene range 4–5): PDZD2.
- chr5:31,820,564–41,071,342, 163 genes, copy number 5–13 (broad region; genes not listed).
- chr5:45,035,199–45,895,970, 6 genes, copy number 10: AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr8:37,717,579–86,343,429, 771 genes, copy number 5–13 (broad region; genes not listed).
- chr12:43,353,866–44,389,762, 13 genes, copy number 5: ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1.
- chr19:27,793,431–27,984,984, 1 gene, copy number 10 (within-gene range 4–10): AC006504.5.
- chr19:27,892,495–30,228,715, 54 genes, copy number 6–14: AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:32,978,592–33,175,799, 5 genes, copy number 8 (within-gene range 3–8): RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88.
- chr19:33,178,056–33,178,651, 1 gene, copy number 8: AC008738.1.
- chr19:34,172,504–34,471,251, 10 genes, copy number 9: LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2.
- chr19:35,666,516–36,173,853, 48 genes, copy number 8: UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3, AF038458.3, AF038458.1, AF038458.2, SDHAF1, SYNE4, AC002116.1, ALKBH6, AC002116.2, CLIP3, THAP8, WDR62, AD000813.1, OVOL3, POLR2I, TBCB, AD001527.2, CAPNS1, AD001527.1, COX7A1, AC002984.1.
- chr19:38,108,500–40,898,282, 159 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr19:42,924,132–43,171,515, 7 genes, copy number 6 (within-gene range 3–6): PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9.
- chr19:44,631,573–44,821,421, 14 genes, copy number 6 (within-gene range 3–6): AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM.
- chr19:49,625,994–50,075,902, 43 genes, copy number 7: AC011495.2, RRAS, SCAF1, IRF3, BCL2L12, PRMT1, MIR5088, ADM5, AC011495.3, CPT1C, AC011495.1, TSKS, RNU6-841P, AP2A1, MIR6799, FUZ, AC006942.1, MED25, MIR6800, PTOV1-AS1, PTOV1, AC018766.1, MIR4749, PTOV1-AS2, PNKP, AKT1S1, TBC1D17, MIR4750, IL4I1, NUP62, AC011452.1, ATF5, MIR4751, SIGLEC11, U3, SIGLEC16, VRK3, Metazoa_SRP, ZNF473, AC010624.3, AC010624.1, AC010624.4, AC010624.2.
- chr19:51,152,923–51,390,591, 24 genes, copy number 7: AC063977.5, AC063977.6, SIGLEC17P, SIGLEC20P, AC063977.4, SIGLEC21P, MIR8074, SIGLEC22P, CD33, SIGLECL1, AC063977.3, LINC01872, SIGLEC24P, IGLON5, VSIG10L, AC008750.2, AC008750.3, ETFB, AC008750.7, AC008750.4, CLDND2, NKG7, LIM2, C19orf84.
- chr19:54,308,915–54,473,296, 16 genes, copy number 13 (within-gene range 4–13): AC245884.11, VN1R104P, AC245884.6, LILRA4, LAIR1, AC245884.4, TTYH1, AC245884.1, AC245884.9, AC245884.10, AC245884.8, LENG8-AS1, AC245884.3, LENG8, LENG9, CDC42EP5.
- chr19:55,006,193–55,312,562, 27 genes, copy number 10 (within-gene range 2–10): AC011476.3, GP6, AC011476.2, RDH13, EPS8L1, PPP1R12C, AC010327.8, AC010327.3, MIR7975, TNNT1, TNNI3, AC010327.2, DNAAF3, AC010327.4, AC010327.1, SYT5, PTPRH, AC010327.7, AC010327.5, TMEM86B, AC010327.6, PPP6R1, MIR6804, MIR6802, MIR6803, HSPBP1, BRSK1.
- chr20:31,303,212–63,980,008, 867 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
